Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3D1, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3D1-01A (Primary Tumor).

[page 1 of 3]
Case Rejected:		

Redacted **al Pathology**
Report
of Pathology

DOB:
Physician:

Collected:

Received:

Case type: Surgical Case

Accession:

***** **MODIFIED REPORT - REVIEW ADDENDUM SECTION** *****

Case has been amended.

DIAGNOSIS

(A) RIGHT NECK CONTENTS:

Eleven lymph nodes, no tumor present (0/11).

(B) TOTAL THYROID GLAND AND LEFT NECK CONTENTS:

PAPILLARY THYROID CARCINOMA, MULTIFOCAL, LEFT LOBE (3.0 CM), CONFINED TO THYROID.

Adenomatous nodules.

Eight lymph nodes, no tumor present (0/8) with one lymph node showing psammoma bodies (levels pending).

Parathyroid tissue present.

Entire report and diagnosis completed by

100-0-3
carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9
A

COMMENT

This report is amended to correct the diagnosis text for Specimen B from "thymoma" to "psammoma".

GROSS DESCRIPTION

(A) RIGHT NECK CONTENTS - Eleven possible lymph nodes are identified (0.1 x 0.1 x 0.1 cm to 0.7 x 0.4 x 0.3 cm).
SECTION CODE: A1, one lymph node bisected; A2, four lymph nodes; A3, six possible lymph nodes.

(B) TOTAL THYROID GLAND AND LEFT NECK CONTENTS - A total thyroidectomy specimen measuring 9.5 x 5.0 x 1.5 cm with attached soft tissue (9.0 x 3.0 x 1.0 cm). The right lobe measures 4.0 x 2.0 x 1.5 cm. The left lobe measures 5.5 x 4.0 x 1.5 cm. The isthmus measures 2.5 x 2.5 x 1.0 cm. In the right upper pole is a 0.3 cm white nodule. In the isthmus is a 1.4 x 0.7 x 0.7 cm homogeneous pink-tan nodule. Also identified is a friable encapsulated tan-pink tumor in the left lower pole (3.0 x 2.0 x 2.0 cm). The remainder of the thyroid parenchyma is homogeneous dark-red. Five lymph nodes are identified in the attached soft tissue ranging in size between 0.3 - 0.8 cm. Representative sections of the largest tumor nodule and non-neoplastic thyroid were submitted to the tumor bank.

SECTION CODE: B1-B3, right lobe from superior to inferior with the nodule in B2; B4-B6, isthmus from right to left; B7-B11, left lobe from superior to inferior with the mass in B9-B11; B12, three lymph nodes; B13, two lymph nodes.

CLINICAL HISTORY

Papillary thyroid cancer

[page 2 of 3]
Surgical Pathology Report

Department of Pathology,
Tel

DOB:
Physician:

Sex: M

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or

Released by:
Released by:

Surgical Pathology Report		Page 2 of 3
File under: Pathology		

[page 3 of 3]
Surgical Pathology Report

Department of Pathology

DOB:
Physician:

Age:

Sex: M

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

ADDENDUM

Addendum completed by

COMMENT

Additional levels reviewed of lymph node with psammomas, no metastatic carcinoma identified. The above diagnosis remains unchanged.

Released by:

Surgical Pathology Report		Page 3 of 3
File under: Pathology		

Source: NCI Genomic Data Commons file e4418b87-136d-483e-8d94-52cee26cf9af (TCGA-EL-A3D1.5CEADB5F-C00E-47CD-B28B-138FAF67CED5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).